CGCI case HTMCP-02-04-01015 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/88b34fb4-7be8-47e7-9c95-f67e562e2a58

Demographics
Sex at birth: female.

Molecular and laboratory tests
- Test (IHC): Positive; Specialized molecular test: P40.

Biospecimens (3 samples)
- Sample HTMCP-02-04-01015-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-04-01015-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-04-01015-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.
